Somatic mutation profile of tumor specimen MP2PRT-PASRGR-TMP1-A (aliquot MP2PRT-PASRGR-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PASRGR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,941 days).
Specimen MP2PRT-PASRGR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 091dd854-f0c9-4a37-a4a7-223964175093.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRGR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRGR-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c3f1cd1-4874-4a8d-be9e-dc6867622a94

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs121918466, CM013420, CM032349, COSV61005872; ClinVar: pathogenic; called by muse, mutect2
- ASTN2 | c.1885G>A p.V629I (on ENST00000313400 / NM_001365069.1; = p.V578I on NM_014010.5) | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV100524290; called by muse, mutect2, varscan2
- CALB2 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371961656; called by muse, mutect2, varscan2
- LIN7C | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs946828342; called by muse, mutect2, varscan2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- BTK | c.1777C>G p.L593V | Missense Mutation (SNP) | VAF 179/417 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CCDC134 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 120/463 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CNTN6 | c.2443T>C p.S815P | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AOC1 | c.585C>G p.G195= | Silent (SNP) | VAF 72/513 reads (14%) | called by muse, mutect2, varscan2
- MED14 | c.1557A>G p.T519= | Silent (SNP) | VAF 222/446 reads (50%) | catalogued as rs747610302; called by muse, mutect2, varscan2
- PLXNA3 | c.2718G>A p.P906= | Silent (SNP) | VAF 21/541 reads (4%) | catalogued as rs781980926; called by muse, mutect2
